Gene-level copy-number profile of tumor specimen MP2PRT-PAPTVF-TMP1-A from MP2PRT case MP2PRT-PAPTVF, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.8 years (2,127 days).
Specimen MP2PRT-PAPTVF-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2411c1c4-e68a-4dd4-bdfd-2fcd49230c96.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAPTVF-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,238 have no estimate.
https://portal.gdc.cancer.gov/files/dede3d66-9ef3-4219-88d1-97aa7584da78

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 132; copy number 1: 277; copy number 2: 57,410; copy number 3: 566.

Homozygous deletions (total copy number 0; autosomes only): 132 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,078,010–89,100,361, 3 genes (within-gene range 0–1): IGKV2-14, IGKV3-15, IGKV1-16.
- chr2:89,192,500–89,213,928, 4 genes (within-gene range 0–1): IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27.
- chr2:89,244,781–89,254,015, 3 genes (within-gene range 0–1): IGKV2-30, IGKV3-31, IGKV1-32.
- chr14:105,672,308–106,481,706, 120 genes (within-gene range 0–2) (broad region; genes not listed).
- chr14:106,531,141–106,538,344, 2 genes (within-gene range 0–1): IGHVIII-47-1, IGHV3-48.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 277. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
